Gene-level copy-number profile of tumor specimen MP2PRT-PAUTJG-TMP1-A from MP2PRT case MP2PRT-PAUTJG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,431 days).
Specimen MP2PRT-PAUTJG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 73e5bfb9-768e-4f5f-9fe8-dd8643143077.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUTJG-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/c3c41cd2-e25d-499a-8fac-8f33f77196f9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 199; copy number 1: 2,969; copy number 2: 55,666; copy number 3: 46.

Homozygous deletions (total copy number 0; autosomes only): 199 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,992,931, 17 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV1-8.
- chr2:89,027,171–89,078,784, 4 genes (within-gene range 0–1): IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14.
- chr2:89,192,500–89,192,752, 1 gene (within-gene range 0–1): IGKV3-25.
- chr2:89,244,781–89,254,015, 3 genes (within-gene range 0–1): IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,968,867–89,990,221, 3 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:113,325,372–113,425,548, 1 gene (within-gene range 0–2): AC016745.1.
- chr2:113,432,600–113,436,042, 1 gene: AC016745.2.
- chr7:142,641,746–142,802,748, 28 genes: TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr14:105,672,308–106,631,653, 134 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,637,718–106,672,073, 7 genes (within-gene range 0–1): IGHVII-60-1, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,195. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
